Gene-level copy-number profile of specimen HCM-SANG-1318-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-1318-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-1318-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b3ef2db-0f6d-4537-aea2-94ff5dd38e24.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1318-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/1f52863d-8f52-4e30-a6b5-d1146398b7cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,333; copy number 2: 27,783; copy number 3: 24,205; copy number 4: 4,372; copy number 5: 1,203.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–2): AL138808.1.
- chr22:18,715,815–18,719,341, 1 gene: PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,203 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–66,607,107, 1,202 genes, copy number 5 (broad region; genes not listed).
- chr20:22,668,480–22,685,344, 1 gene, copy number 5: LINC01747.

Autosomal genes at a single copy (total copy number 1): 63. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
